ALCHEMIST case ALCH-AEJZ — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/fb3ac0b5-348f-4125-ae41-b4ec3cd3016c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Non-small cell carcinoma: Age at diagnosis: 74.3 years (27,152 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AEJZ-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AEJZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AEJZ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 42; Percent tumor nuclei: 40; Percent normal cells: 40; Percent necrosis: 8; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
